Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7424, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7424-01A (Primary Tumor).

DIAGNOSIS

(A) RIGHT LARYNX:

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

(B) ~~RIGHT EXTENDED RADICAL NECK AND LEFT MODIFIED NECK DISSECTION AND TOTAL LARYNGECTOMY:~~

INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
ARISING IN THE RIGHT PYRIFORM SINUS (2.4 X 2.0 X 1.5 CM).
(SEE COMMENT)

PERINEURAL INVASION PRESENT.

METASTATIC SQUAMOUS CELL CARCINOMA PRESENT IN RIGHT SUBDIGASTRIC
AND MIDJUGULAR LYMPH NODES (SUBMENTAL/SUBMAXILLARY LYMPH
NODES: 0/3). (SEE COMMENT)

One left cervical lymph node, no tumor present.

Superior mucosal, inferior tracheal, and peripheral soft tissue
margins, no tumor present.

Left true and false vocal cords, left pyriform sinus, epiglottis
and anterior commissure, no tumor present.

Multinodular goiter in right lobe of thyroid, no tumor present.

(C) TEETH:

Teeth (gross only).

COMMENT

There is a 2.4 cm tumor mass obliterating the right pyriform sinus
and right aryepiglottic fold that extends into the submucosa of the right
true and false vocal cord and within less than 1.0 mm of the adjacent soft
tissue margin.

There is a 5.0 cm tumor mass in the level 3 and 4 areas of the right
neck dissection which appears to represent a mass of matted lymph nodes
almost completely replaced by carcinoma.

SPECIMEN

(A) RIGHT LARYNX:

(B) RIGHT EXTENDED RADICAL NECK AND LEFT MODIFIED NECK DISSECTION AND TOTAL

(C) TEETH:

SNOMED CODES

T-24100,M-80703

Source: NCI Genomic Data Commons file cf6a0120-770a-4a90-8ee1-53ce52c264c1 (TCGA-CV-7424.DFC51805-6878-41DE-B0EF-37CB29776FC5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).